TCGA case TCGA-58-8388 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Thoraxklinik at University Hospital Heidelberg. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5489b76d-68d9-48c3-8961-4a147bb23216

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 60 years; Vital status: Dead; Days to death: 412 days (1.1 years).

Diagnoses (1)
1. Basaloid squamous cell carcinoma: ICD-O-3 morphology code: 8083/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 60.1 years (21,949 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 412 days (1.1 years); Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 378 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 412 days (1.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Preoperative.

Other clinical attributes
- FEV1/FVC before bronchodilator (%): 65; FEV1 before bronchodilator (% of reference): 71.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 80.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-58-8388-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.5.
  Slide TCGA-58-8388-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 72; Percent normal cells: 5; Percent necrosis: 15; Percent stromal cells: 15; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2.
  Slide TCGA-58-8388-01A-01-BS1: Section location: Bottom; Percent tumor cells: 78; Percent tumor nuclei: 85; Percent normal cells: 2; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 2.
- Sample TCGA-58-8388-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-58-8388-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-58-8388-11A-01-TS1: Section location: Top; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 10.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Basaloid Squamous Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Upper; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 412 days; disease-specific survival: no event (censored), 412 days; disease-free interval: no event (censored), 412 days; progression-free interval: no event (censored), 412 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-58-8388-01A-11D-2322-01): tumor purity 0.71, ploidy 1.9, whole-genome doublings 0.
